Surgical pathology report (de-identified scan), TCGA case TCGA-DD-AADF, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site Mayo Clinic - Rochester, specimen TCGA-DD-AADF-01A (Primary Tumor).

[page 1 of 2]
ICD-O-3
Carcinoma, hepatocellular NOS
Site Liver C22.0 8170/3
Qd 5/19/14

CLINICAL DIAGNOSIS: HCC

Specimen : liver

Gross Photo :

GROSS:

Specimen status: Fresh

Operation: Right anterior sectionectomy (segment 5, partial segment 8)

Organ: Liver (8.5 x 8.0 x 4.0 cm, 121.7 gm)

Gallbladder (10.5 cm in length, 4.0 cm in diameter)

[Liver]

Lesion: A hepatic mass

Size: 4.0 x 3.0 x 3.0 cm

Cut surface: Well demarcated, mahogany and nodular

Gross type: Multinodular confluent

Extent: Confined to the hepatic parenchyma

Serosal surface: Bulging but smooth

Resection margin: Not involved, grossly (safety margin: 0.8 cm)

Remaining parenchyme: Cirrhosis

[Gallbladder]

Serosal surface: Yellowish pink and smooth

Mucosal surface: Dark geen and velvety

Stone: Three, black and hard (0.8 x 0.4 x 0.2 cm in aggregates)

Representative sections are submitted.

Gross photo: Present

Blocks

T1-4, mass of liver x 4

RM, tumor with resection margin x 1

L, nontumorous liver parenchyme x 1

GB, gallbladder x 1

MICROSCOPIC:

Tumor type: Hepatocellular carcinoma

Edmondson-steiner grade

The worst differentiation IV

The major differentiation III

Histologic type: Trabecular, pseudoglandular and cystic formation

Fatty change: No

Fibrous capsule formation: Yes

Capsular infiltration: Yes

Septum formation: Yes

Surgical resection margin invasion: No

Serosal invasion: No

[page 2 of 2]
Portal vein invasion: No
Vascular invasion: No
Bile duct invasion: No
Remaining liver parenchyme: Cirrhosis

NOT reported. Gross:

cervix,smear,senile atrophy

liver,ectomy,hepatocellular carcinoma

T56000, P10, M81703

gallbladder,ectomy,chronic cholecystitis,cholelithiasis

T57000, P10, M43005, M30011

DIAGNOSIS:

Liver, segment 5 and 8, right anterior sectionectomy:
Hepatocellular carcinoma

Gallbladder, cholecystectomy:
Chronic cholecystitis
Cholelithiasis

Suggestion :

Source: NCI Genomic Data Commons file ac7b645b-8d8b-4196-99de-67bccb664303 (TCGA-DD-AADF.046D3A59-FFB8-40B1-8ED2-6853F42CF611.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).